Somatic mutation profile of tumor specimen TARGET-30-PAUICI-01A (aliquot TARGET-30-PAUICI-01A-01D) from TARGET case TARGET-30-PAUICI, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Posterior mediastinum; Age at diagnosis: 4.1 years (1,495 days).
Specimen TARGET-30-PAUICI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0fecbe5-ddd1-446f-8cef-110a12e80aec.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUICI-10A (Blood Derived Normal), aliquot TARGET-30-PAUICI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/246e0796-af06-4efc-b418-2f96baafa977

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, In Frame Del 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD30A | c.1989A>C p.Q663H (on ENST00000611781; = p.Q607H on NM_052997.2) | Missense Mutation (SNP) | VAF 78/190 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV64604903; called by muse, mutect2, varscan2
- MACF1 | c.14036G>A p.R4679H (on ENST00000372915; = p.R2612H on NM_012090.5) | Missense Mutation (SNP) | VAF 67/177 reads (38%) | catalogued as rs143981052; called by muse, mutect2, varscan2
- KRAS | c.405_407del p.R135del | In Frame Del (DEL) | VAF 76/202 reads (38%) | called by pindel, varscan2
- TP53 | c.*544G>T | 3'UTR (SNP) | VAF 58/136 reads (43%) | catalogued as COSV52758979; called by muse, mutect2, varscan2
- USP6 | c.-363C>A | 5'UTR (SNP) | VAF 40/98 reads (41%) | catalogued as COSV51475656; called by muse, mutect2, varscan2
